Somatic mutation profile of tumor specimen TCGA-VS-A9UY-01A (aliquot TCGA-VS-A9UY-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 29.3 years (10,707 days).
Specimen TCGA-VS-A9UY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de7da335-8560-4f55-9ecd-d5efe69b1068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UY-10A (Blood Derived Normal), aliquot TCGA-VS-A9UY-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51fc2ca3-993e-49d5-824d-0a4f46adc0e8

The open-access MAF lists 124 somatic variants for this specimen: 90 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 33, Nonsense Mutation 10, In Frame Del 3, Frame Shift Del 2, Frame Shift Ins 2, Translation Start Site 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC093155.3 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as COSV100777765; called by muse, mutect2, varscan2
- ACER2 | c.693C>G p.Y231* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100575822; called by muse, mutect2, varscan2
- ALAS1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as rs769075509, COSV59626822; called by muse, mutect2, varscan2
- ANKRD50 | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101538984; called by muse, mutect2, varscan2
- ATP13A4 | c.3277G>C p.E1093Q | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as COSV100710145, COSV100710427; called by muse, mutect2, varscan2
- ATP8B1 | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.969); catalogued as COSV99377369; called by muse, mutect2, varscan2
- ATP8B1 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV52175123, COSV99377372; called by muse, mutect2
- BPIFA2 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99487901; called by muse, mutect2
- CARD9 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs751776187, COSV100047334; called by muse, mutect2, varscan2
- CASP7 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.941); catalogued as COSV100614914; called by muse, mutect2, varscan2
- CCDC120 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1557080420, COSV100900653; called by muse, mutect2, varscan2
- CEP120 | c.1888T>A p.S630T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV100071175; called by muse, mutect2, varscan2
- CNTNAP3 | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99904983; called by muse, mutect2, varscan2
- CTSF | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100074332; called by muse, mutect2, varscan2
- DAZAP1 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245296; called by muse, mutect2
- DENND4B | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100768736; called by muse, mutect2, varscan2
- DLGAP1 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100227931, COSV100231672; called by muse, mutect2
- EHMT1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100603962; called by muse, mutect2, varscan2
- EP300 | c.4680G>C p.K1560N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV54335956; called by muse, mutect2, varscan2
- EPHA1 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs138935836; called by muse, mutect2, varscan2
- EPRS1 | c.4414C>G p.P1472A | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs886842952, COSV100859402; called by muse, mutect2, varscan2
- FAM133B | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as rs997294321, COSV101300213; called by muse, mutect2, varscan2
- FAM181B | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780433938, COSV100235010; called by muse, mutect2, varscan2
- FSTL4 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV99532907; called by muse, mutect2, varscan2
- GARNL3 | c.2207T>G p.F736C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as COSV100150363; called by muse, mutect2, varscan2
- GOLGB1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100511055; called by muse, mutect2, varscan2
- H2AC4 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 36/50 reads (72%) | catalogued as rs765439690; called by pindel, varscan2
- HDAC5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.968); catalogued as COSV99870703; called by muse, mutect2, varscan2
- HDAC6 | c.1347C>A p.N449K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV100490932; called by muse, mutect2, varscan2
- HUWE1 | c.9743G>A p.S3248N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99472745; called by muse, mutect2, varscan2
- IGF2R | c.2503G>C p.E835Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100807520; called by muse, mutect2, varscan2
- IGHV5-51 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199503234; called by muse, mutect2, varscan2
- IHO1 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99605956, COSV99606040, COSV99606252; called by muse, mutect2
- KCNA2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100316015; called by muse, mutect2, varscan2
- KHDRBS2 | c.349A>T p.R117W | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834508; called by muse, mutect2, varscan2
- LAMA3 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs367796914, COSV100557006; called by muse, mutect2, varscan2
- LTBP4 | c.4120G>A p.E1374K (on ENST00000308370 / NM_001042544.1; = p.E1337K on NM_003573.2) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99194372; called by muse, mutect2, varscan2
- MAP4K3 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99810539; called by muse, mutect2, varscan2
- MDGA1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs952123366, COSV99777014; called by muse, mutect2, varscan2
- MYOT | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296398; called by muse, mutect2, varscan2
- OR10J1 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV101419906; called by muse, mutect2, varscan2
- OR1B1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs543380400, COSV59172018; called by muse, mutect2, varscan2
- OR9A4 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs782435363, COSV71884971; called by muse, mutect2, varscan2
- OSBPL3 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100514214; called by muse, mutect2, varscan2
- PCYT2 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100325996, COSV58711013; called by muse, mutect2, varscan2
- PDHA1 | c.1104C>G p.I368M | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100134913; called by muse, mutect2, varscan2
- PFDN6 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101004801; called by muse, mutect2, varscan2
- PKM | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs1315530657, COSV100064897; called by muse, mutect2
- PLCB4 | c.3518C>T p.T1173I (on ENST00000278655 / NM_182797.3; = p.N1185= on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1176712700, COSV99595772; called by muse, mutect2, varscan2
- PLEKHO1 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99215272; called by muse, mutect2, varscan2
- PLXND1 | c.4216A>G p.M1406V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144355531, COSV100139907; called by muse, mutect2, varscan2
- PPIE | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100180087; called by muse, mutect2
- PRB2 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1302477750, COSV101231430; called by muse, varscan2
- PRKCZ | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV101057860; called by muse, mutect2, varscan2
- PROKR2 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV54089194, COSV99450353; called by muse, mutect2, varscan2
- RAB9B | c.453A>T p.L151F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99686072; called by muse, mutect2, varscan2
- RAI14 | c.2694G>C p.L898F | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54304892; called by muse, mutect2, varscan2
- RALBP1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as COSV99191958; called by muse, mutect2
- RAP1GAP | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265397; called by muse, mutect2, varscan2
- RIMBP2 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as rs778628806, COSV55474568; called by muse, mutect2, varscan2
- RPL19 | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV56634863, COSV99841489; called by muse, mutect2, varscan2
- RPS6KA5 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1199820517, COSV100002707; called by muse, mutect2, varscan2
- S1PR2 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100495331; called by muse, mutect2, varscan2
- SEZ6L | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV50660421; called by muse, mutect2, varscan2
- SGO2 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV100764700; called by muse, mutect2, varscan2
- SPACA7 | c.575A>C p.Q192P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99366684; called by muse, mutect2, varscan2
- SPEN | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV65368701; called by muse, mutect2, varscan2
- STAT5B | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as COSV53180428; called by muse, mutect2, varscan2
- TAAR1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs1313985196, COSV99257634; called by muse, mutect2, varscan2
- TIMP3 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99831188; called by muse, mutect2, varscan2
- TMEM225 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV100902822; called by muse, mutect2, varscan2
- TMX4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV99851522; called by muse, mutect2, varscan2
- TPBG | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100869727, COSV100869788; called by muse, mutect2, varscan2
- TRBV5-1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs773023358; called by muse, mutect2, varscan2
- TTLL13P | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs140261915; called by muse, mutect2, varscan2
- WBP1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as rs1368212533, COSV99270576; called by muse, mutect2
- WIZ | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99653346; called by muse, mutect2, varscan2
- ZFP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV60034453; called by muse, mutect2, varscan2
- ZNF189 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs772768957, COSV99407223; called by muse, mutect2, varscan2
- BEST1 | c.1539dup p.E514* | Frame Shift Ins (INS) | VAF 13/83 reads (16%) | called by pindel, varscan2
- CLASP2 | c.3497_3509del p.T1166Rfs*11 (on ENST00000359576; = p.T1165Rfs*11 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/88 reads (44%) | called by mutect2, pindel, varscan2
- EP300 | c.3707dup p.N1236Kfs*2 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- NECAB1 | c.24_32del p.P9_S11del | In Frame Del (DEL) | VAF 39/107 reads (36%) | called by mutect2, pindel, varscan2
- OVOL1 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- PTPN20 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA5 | c.576_584del p.L193_V195del | In Frame Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- TBX22 | c.832G>C p.A278P | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TBX22 | c.837del p.G280Dfs*16 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | called by mutect2, pindel, varscan2
- YY2 | c.388_389insAATCAA p.S129_T130insKS | In Frame Ins (INS) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- AMOT | c.1611C>T p.I537= (on ENST00000371959 / NM_001113490.1; = p.I128= on NM_133265.3) | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100495183; called by muse, mutect2, varscan2
- C9 | c.642C>T p.T214= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs903055186, COSV99662138; called by muse, mutect2, varscan2
- CBX8 | c.669A>C p.G223= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99485892; called by muse, mutect2, varscan2
- CCDC22 | c.756G>A p.L252= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100873180; called by muse, mutect2, varscan2
- CNOT3 | c.456G>A p.Q152= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs770478177, COSV99651980; called by muse, mutect2, varscan2
- COL6A6 | c.5385C>T p.P1795= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1176535234, COSV100650345; called by muse, mutect2, varscan2
- CSMD3 | c.10797A>G p.K3599= (on ENST00000297405 / NM_001363185.1; = p.K3430= on NM_052900.3) | Silent (SNP) | VAF 93/129 reads (72%) | catalogued as COSV52133513, COSV99836776; called by muse, mutect2, varscan2
- DOCK7 | c.2652G>T p.V884= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as rs368758793; called by muse, mutect2, varscan2
- DOP1A | c.2073C>G p.L691= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV52718781; called by muse, mutect2, varscan2
- EPPK1 | c.6471C>T p.L2157= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV101599868; called by muse, mutect2, varscan2
- GON4L | c.1308C>T p.I436= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55190173; called by muse, mutect2, varscan2
- GPR142 | c.300G>A p.V100= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100170846; called by muse, mutect2, varscan2
- HAUS6 | c.2865A>G p.R955= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100997858; called by muse, mutect2, varscan2
- ITPR2 | c.7839T>C p.Y2613= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV101190027; called by muse, mutect2, varscan2
- KCNA5 | c.861G>A p.A287= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52907103; called by muse, mutect2, varscan2
- KCNH6 | c.1311G>A p.L437= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100121109; called by muse, mutect2, varscan2
- KLHDC7B | c.297G>A p.A99= (on ENST00000395676; = p.A740= on NM_138433.5) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs771839566, COSV101192950, COSV67464973; called by muse, mutect2, varscan2
- MRGPRX3 | c.90C>T p.F30= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs773378884, COSV101283556; called by muse, mutect2, varscan2
- MYLK | c.4983C>T p.F1661= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs367656778; called by muse, mutect2, varscan2
- OGDHL | c.2340G>A p.A780= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs771265292, COSV65102561; called by muse, mutect2, varscan2
- PLA1A | c.1026C>G p.L342= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99845907; called by muse, mutect2, varscan2
- PPL | c.3753C>T p.L1251= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99278128, COSV99278732; called by muse, mutect2, varscan2
- PSG11 | c.984T>A p.T328= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100105880; called by muse, mutect2, varscan2
- SBF2 | c.5484C>T p.C1828= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs149571145; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC16A12 | c.894C>T p.S298= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100370274; called by muse, mutect2, varscan2
- TDRD5 | c.432G>A p.A144= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs369571297; called by muse, mutect2, varscan2
- TECPR1 | c.291C>T p.D97= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs1249615708, COSV101130552; called by muse, mutect2, varscan2
- TMEM19 | c.969C>T p.L323= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV99876993; called by muse, mutect2, varscan2
- UBA52 | c.129G>A p.L43= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99723682; called by muse, mutect2, varscan2
- USH2A | c.6576C>A p.V2192= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100236531, COSV56393923; called by muse, mutect2, varscan2
- USP37 | c.339G>A p.P113= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs200987431; called by muse, mutect2, varscan2
- ZNF608 | c.1530G>C p.L510= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV100101832; called by muse, mutect2, varscan2
- ZSWIM5 | c.3154C>T p.L1052= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99870253; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-13T>G | Intron (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100025552; called by muse, mutect2, varscan2
